TCGA case TCGA-FW-A3R5 — Skin Cutaneous Melanoma (TCGA-SKCM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Nevi and Melanomas; Primary site: Lymph nodes; Tissue source site: International Genomics Consortium. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/e5bc45ce-8a14-40b5-b9b5-ce45609fef3a

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 68 years; Vital status: Alive.

Diagnoses (4)
1. Malignant melanoma, NOS (the primary disease): ICD-O-3 morphology code: 8720/3; ICD-10 code: C77.0; Tissue or organ of origin: Skin, NOS; Site of resection or biopsy: Lymph nodes of head, face and neck; Classification of tumor: Progression; Age at diagnosis: 69.9 years (25,535 days); Days to diagnosis: 667 days (1.8 years); Prior treatment: No; Days to last follow up: 1,124 days (3.1 years).
   Recorded as not given: Pharmaceutical Therapy, NOS, prior to procurement; Radiation Therapy, NOS, prior to procurement.
2. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; Tissue or organ of origin: Head, face or neck, NOS; Laterality: Left; Classification of tumor: Prior primary; AJCC staging edition: 7th; AJCC pathologic T: Tis; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage 0.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.
3. Malignant melanoma, NOS: Tissue or organ of origin: Skin, NOS; Classification of tumor: primary; Sites of involvement: Skin, Head and Neck.
   Recorded as not given: Radiation Therapy, NOS.
4. Malignant melanoma, NOS: ICD-O-3 morphology code: 8720/3; Tissue or organ of origin: Skin, NOS; Classification of tumor: primary; Age at diagnosis: 68.1 years (24,868 days); Year of diagnosis: 2010; AJCC staging edition: 7th; AJCC pathologic T: TX; AJCC pathologic N: N2; AJCC pathologic M: M0; AJCC pathologic stage: Stage III; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: No; Melanoma known primary: Yes.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Therapeutic agents: Interferon; Days to treatment start: 714 days (2.0 years); Days to treatment end: 993 days (2.7 years); Treatment outcome: Complete Response.

Follow-up (2 entries)
- Days to follow up: 1,124 days (3.1 years); Disease response: Tumor Free.
- Follow-up contact recording only the day: day 697.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-FW-A3R5-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-FW-A3R5-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT; Initial weight: 30 mg.
  Slide TCGA-FW-A3R5-06A-01-TS1: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 20; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-FW-A3R5-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.
- Sample TCGA-FW-A3R5-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 70 mg.
  Slide TCGA-FW-A3R5-11A-01-TS1: Section location: Top; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 100; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; History neoadjuvant treatment: No; Radiation therapy to primary: No; Primary location: Regional Lymph Node; Primary melanoma skin type: Non-glabrous skin; Prior radiation therapy: No; History neoadjuvant treatment: No.
- Sites of primary melanomas: Primary multiple at diagnosis: No; Primary at diagnosis count: 1.
- Sites of primary melanomas, Site: Submitted tumor site: Head and Neck; Melanoma primary count: 1.
- Follow-up form: Lost to follow-up: No; Tumor status: Tumor free; Subsequent known primaries: No.
- Other malignancy form: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Head/Neck; Other malignancy histological type: Squamous Cell Carcinoma, Not Otherwise Specified.

GDC annotations on this case (curator notes; quoted as recorded):
- Prior malignancy: Patient had a prior squamous cell carincoma of the cheek. No radiation or systemic chemotherapy.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,124 days; disease-specific survival: no event (censored), 1,124 days; progression-free interval: no event (censored), 1,124 days.
